Somatic mutation profile of tumor specimen C3L-06540-54 (aliquot CPT0357910002) from CPTAC case C3L-06540, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 38.5 years (14,062 days).
Specimen C3L-06540-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36371aab-59a3-48a5-9a29-7925947dfcdf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06540-51 (Buccal Cell Normal), aliquot CPT0357880003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cb093851-a08a-4df9-a9dc-e8c0bf7662df

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 2, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAJB6 | c.575C>A p.S192* | Nonsense Mutation (SNP) | VAF 12/78 reads (15%) | catalogued as COSV51099472; called by muse, mutect2, varscan2
- EPHA10 | c.1663G>C p.A555P | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.828); catalogued as COSV57626666; called by muse, mutect2, varscan2
- OR5L2 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 69/149 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs200162111, COSV65723663; called by muse, mutect2, varscan2
- GPR137 | c.818A>T p.Y273F | Missense Mutation (SNP) | VAF 118/255 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RASL12 | c.116A>G p.K39R | Missense Mutation (SNP) | VAF 69/176 reads (39%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- ZMYM6 | c.3563T>C p.F1188S | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ARHGEF40 | c.859C>A p.R287= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as rs761039757; called by muse, mutect2, varscan2
- FGA | c.2187G>A p.E729= | Silent (SNP) | VAF 91/266 reads (34%) | catalogued as rs1289107077, COSV57395199; called by muse, mutect2, varscan2
- PDPK1 | c.1344-2992G>A | Intron (SNP) | VAF 19/293 reads (6%) | catalogued as rs746348731; called by muse, mutect2
- SAMD13 | c.226-4411G>C | Intron (SNP) | VAF 58/114 reads (51%) | called by muse, varscan2
